TCGA case TCGA-24-1557 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7dcc809b-e33a-4453-b92a-c00786f48cb0

Demographics
Sex at birth: female; Race: white; Age at index: 49 years; Vital status: Dead; Days to death: 1,213 days (3.3 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 49.1 years (17,943 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 281 days; Number of cycles: 12; Treatment dose: 6,250 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 281 days; Number of cycles: 8; Treatment dose: 3,392 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Treatment intent type: Adjuvant; Days to treatment start: 27 days; Days to treatment end: 281 days; Number of cycles: 4; Treatment dose: 15 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 300 days; Days to treatment end: 347 days; Number of cycles: 3; Treatment dose: 32 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 368 days (1.0 years); Days to treatment end: 445 days (1.2 years); Number of cycles: 3; Treatment dose: 10,980 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 368 days (1.0 years); Days to treatment end: 445 days (1.2 years); Number of cycles: 3; Treatment dose: 175 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 462 days (1.3 years); Days to treatment end: 623 days (1.7 years); Number of cycles: 8; Treatment dose: 5,350 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 462 days (1.3 years); Days to treatment end: 623 days (1.7 years); Number of cycles: 8; Treatment dose: 2,600 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 644 days (1.8 years); Days to treatment end: 727 days (2.0 years); Number of cycles: 4; Treatment dose: 1,300 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 754 days (2.1 years); Days to treatment end: 798 days (2.2 years); Number of cycles: 3; Treatment dose: 46 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Treatment intent type: Palliative; Days to treatment start: 765 days (2.1 years); Days to treatment end: 873 days (2.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 875 days (2.4 years); Days to treatment end: 1,008 days (2.8 years); Number of cycles: 7; Treatment dose: 670 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 875 days (2.4 years); Days to treatment end: 1,008 days (2.8 years); Number of cycles: 7; Treatment dose: 12,240 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,027 days (2.8 years); Days to treatment end: 1,069 days (2.9 years); Number of cycles: 3; Treatment dose: 424 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,090 days (3.0 years); Days to treatment end: 1,154 days (3.2 years); Number of cycles: 4; Treatment dose: 2,315 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,090 days (3.0 years); Days to treatment end: 1,154 days (3.2 years); Number of cycles: 4; Treatment dose: 1,300 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 50.3 years (18,390 days); Days to diagnosis: 447 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (2 entries)
- Day 447 (post initial treatment): Progression or recurrence: Yes; Days to progression: 447 days (1.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,213 days (3.3 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-24-1557-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 8.
  Slide TCGA-24-1557-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-24-1557-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 8: Pharmaceutical therapy drug name: Gemzar.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,213 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,213 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 447 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-24-1557-01): tumor purity 0.91, ploidy 3.24, whole-genome doublings 1 (call status: legacy_call).
